CPTAC case C3L-05987 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bde4d324-c7f2-43d7-a7c2-a6b6a2fd5f43

Demographics
Sex at birth: male; Race: white; Year of birth: 1939; Vital status: Dead; Days to death: 262 days; Year of death: 2020; Cause of death: Cancer Related; Country of birth: Bulgaria.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 80.0 years (29,202 days); Year of diagnosis: 2019; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: TX; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 262 days; Progression or recurrence: yes; Days to last follow up: 193 days; Tumor focality: Multifocal; Ulceration indicator: No.
   Pathology details: Greatest tumor dimension: 1.5 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 1; Margin status: Indeterminate.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (1 entry)
- Days to follow up: 193 days; Disease response: With Tumor; Karnofsky performance status: 0; ECOG performance status: 5.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-05987-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -4 days; Initial weight: 220 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-05987-22: Section location: Lymph node; Percent tumor nuclei: 80; Percent necrosis: 10.
- Sample C3L-05987-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -5 days; Method of sample procurement: Blood Draw.
